Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8YQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8YQ-01A (Primary Tumor).

Surgical Pathology Report

PATIENT INFORMATION	PHYSICIAN INFORMATION
Patient Name: [REDACTED] DOB: [REDACTED] Age: [REDACTED] SSN: [REDACTED] Sex: Female	Client#: [REDACTED] Submitted By: [REDACTED] Practice: [REDACTED] Location: [REDACTED] Fax: [REDACTED]

Accession#: [REDACTED]
ical DX/History: [REDACTED]
PreOp DX: Post menopausal bleeding
PostOp DX: Same as the preoperative diagnosis

Collected: [REDACTED] Received: [REDACTED]

PATHOLOGY RESULTS

A: CERVIX, 6 O'CLOCK, BIOPSY
CARCINOMA, SQUAMOUS CELL

B: ENDOCERVIX, CURETTAGE
CARCINOMA, SQUAMOUS CELL

ICD-O-3
Carcinoma, squamous cell NOS
Site Cervix NOS
8070/3
853.9
12/11/14

Comment / Micro Findings:

The biopsy and curettage correlate with the patient's previous Pap smear ([REDACTED]). The depth of invasion cannot be determined in this specimen. [REDACTED] office was notified at [REDACTED].

Additional History:

Slide total = 4.

Gross:

The specimen is received in fixative in two (2) containers both labeled with the patient's name.

A. Specimen A is labeled "cervical bx at 6 o'clock". The specimen consists of a 0.8 cm piece of tan tissue. Entirely submitted in cassette A1.

B. Specimen B is labeled "ECC". The specimen consists of a 1 cc aggregate of tan mucoid material. Entirely submitted in cassette B1.

Performed By: [REDACTED]

Micro Description:

Unless 'gross exam' is specified, the final diagnosis (pathology results) for each specimen is based on a microscopic examination of the tissues or preparations from these tissues.

Diagnostic Pathologist(s): [REDACTED]

** = designates that this report is electronically signed by secret password.

Source: NCI Genomic Data Commons file 7a8ce1b4-c9ec-43a5-be62-b62b9bba5677 (TCGA-C5-A8YQ.BF1A25FA-5A13-4C4B-8686-342B180FD72F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).